Somatic mutation profile of tumor specimen TCGA-06-5408-01A (aliquot TCGA-06-5408-01A-01D-1696-08) from TCGA case TCGA-06-5408, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.9 years (20,063 days).
Specimen TCGA-06-5408-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9113c48-4abd-443d-b154-0035b935a806.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-5408-10A (Blood Derived Normal), aliquot TCGA-06-5408-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b25dc783-1dac-420f-b90c-5845e2e3996f

The open-access MAF lists 45 somatic variants for this specimen: 34 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 10, 3'Flank 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC4 | c.3309C>G p.I1103M | Missense Mutation (SNP) | VAF 5/142 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV65309782; called by muse, mutect2
- ACCS | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs772190083, COSV55457191; called by muse, mutect2, varscan2
- ADGRL3 | c.755A>G p.E252G (on ENST00000506720 / NM_001322402.2; = p.E184G on NM_015236.6) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72265850; called by muse, mutect2, varscan2
- CARD6 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV54564242; called by muse, mutect2, varscan2
- CCR1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs747244913, COSV56121663; called by muse, mutect2, varscan2
- CFAP70 | c.2308C>T p.R770W | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs141991496; called by muse, mutect2, varscan2
- CNGA4 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs1255071797, COSV66005087, COSV66006082; called by muse, mutect2, varscan2
- CXCR2 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.119); catalogued as rs1014647889, COSV59279796; called by muse, mutect2, varscan2
- CYP11A1 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs974871680, COSV51430685; called by muse, mutect2, varscan2
- CYP4F12 | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs375976293, COSV61172372; called by muse, mutect2, varscan2
- DNAJB7 | c.330C>A p.H110Q | Missense Mutation (SNP) | VAF 76/93 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs1295211358, COSV53420719, COSV53420815; called by muse, mutect2, varscan2
- FREM2 | c.6307C>T p.R2103C | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs368450271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAS7 | c.1216T>C p.L406= (on ENST00000432992 / NM_201433.2; = p.L266= on NM_003644.3) | Splice Region (SNP) | VAF 34/95 reads (36%) | catalogued as rs778591317, COSV60431677; called by muse, mutect2, varscan2
- KEL | c.923A>G p.K308R | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs1562962327, COSV62333386; called by muse, mutect2, varscan2
- MBOAT1 | c.943A>G p.S315G | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs150163538; called by muse, mutect2, varscan2
- MED4 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV51638673; called by muse, mutect2, varscan2
- MTERF1 | c.544T>C p.F182L | Missense Mutation (SNP) | VAF 90/206 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.463); catalogued as COSV61097881; called by muse, mutect2, varscan2
- OAS2 | c.2015G>T p.G672V | Missense Mutation (SNP) | VAF 32/438 reads (7%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.702); catalogued as COSV60801169; called by muse, mutect2
- OR5L2 | c.176T>A p.V59E | Missense Mutation (SNP) | VAF 120/255 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV65723388; called by muse, mutect2, varscan2
- RAG2 | c.1381C>A p.L461M | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57556450; called by muse, mutect2, varscan2
- RTN1 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377312291, COSV50718870; called by muse, mutect2, varscan2
- RXYLT1 | c.1094C>T p.T365I | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.395); catalogued as rs758204536, COSV54167580; called by muse, mutect2, varscan2
- SLC22A9 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.918); catalogued as rs760458545, COSV54165823; called by muse, mutect2, varscan2
- SLC49A3 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV59139397; called by muse, mutect2, varscan2
- SLC5A4 | c.569T>C p.V190A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV56668477; called by muse, mutect2
- STK26 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 105/203 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as rs764289150, COSV61228809; called by muse, mutect2, varscan2
- STYK1 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 113/329 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554694983, COSV50012296; called by muse, mutect2, varscan2
- TRIM62 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs762636288, COSV52220373; called by muse, mutect2, varscan2
- UBN2 | c.3869C>T p.T1290I | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56027795; called by muse, mutect2, varscan2
- VPS50 | c.273C>G p.D91E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.729); catalogued as COSV52492688; called by muse, mutect2, varscan2
- WDR90 | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs760505497, COSV53466487; called by muse, mutect2, varscan2
- WNT2 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as rs376068978, COSV55411972; called by muse, mutect2, varscan2
- XIRP2 | c.230A>G p.E77G | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV54683352; called by muse, mutect2, varscan2
- ATP10A | c.1339_1340dup p.E448* | Frame Shift Ins (INS) | VAF 76/184 reads (41%) | called by mutect2, pindel, varscan2
- CAD | c.4275C>T p.P1425= | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as rs1482881375, COSV53023716; called by muse, mutect2, varscan2
- FLG2 | c.5238A>G p.G1746= | Silent (SNP) | VAF 21/404 reads (5%) | catalogued as rs747505339, COSV66166734; called by muse, mutect2
- GEM | c.675G>A p.Q225= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV52596624; called by muse, mutect2, varscan2
- MMP2 | c.1221C>T p.H407= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as rs772843973, COSV54599130; called by muse, mutect2, varscan2
- MMP21 | c.597G>A p.A199= | Silent (SNP) | VAF 28/31 reads (90%) | catalogued as rs138636566, COSV64288669; called by muse, mutect2, varscan2
- MUC16 | c.2958A>T p.S986= | Silent (SNP) | VAF 21/421 reads (5%) | catalogued as COSV67445744; called by muse, mutect2
- NF1 | c.4548G>A p.E1516= (on ENST00000358273 / NM_001042492.3; = p.E1495= on NM_000267.3) | Silent (SNP) | VAF 16/230 reads (7%) | catalogued as COSV62193505; called by muse, mutect2
- PRR23B | c.408C>T p.V136= | Silent (SNP) | VAF 55/111 reads (50%) | catalogued as COSV61493184; called by muse, mutect2, varscan2
- SCN10A | c.2499C>T p.H833= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs995722247, COSV71860302; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF92 | c.1728C>A p.S576= (on ENST00000328747 / NM_152626.4; = p.S507= on NM_007139.4) | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as COSV60873036; called by muse, mutect2, varscan2
- VEGFA | chr6:43784622 A>T | 3'Flank (SNP) | VAF 31/80 reads (39%) | catalogued as COSV57877726; called by muse, mutect2, varscan2
